Somatic mutation profile of tumor specimen MP2PRT-PAPCAC-TMP1-A (aliquot MP2PRT-PAPCAC-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPCAC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (472 days).
Specimen MP2PRT-PAPCAC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b91ee122-97e2-4043-ad54-1498e2eeeb4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPCAC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPCAC-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41822f24-96d9-47c4-b134-1cbe480a305d

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 169/501 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772685782; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 135/521 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 163/488 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, mutect2, varscan2
- ANKRD13B | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.223); catalogued as rs199786725, COSV67473712; called by muse, mutect2, varscan2
- CAMP | c.493C>T p.R165W (on ENST00000296435; = p.R162W on NM_004345.5) | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs374668266; called by muse, mutect2, varscan2
- PPP1R14A | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 231/576 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs1168277269; called by muse, mutect2, varscan2
- IFT81 | c.1224T>G p.S408R | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- PDGFD | c.942G>A p.R314= | Silent (SNP) | VAF 167/417 reads (40%) | called by muse, mutect2, varscan2
